Somatic mutation profile of tumor specimen TARGET-10-PARBPX-09A (aliquot TARGET-10-PARBPX-09A-01D) from TARGET case TARGET-10-PARBPX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,268 days).
Specimen TARGET-10-PARBPX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1345a28-f7a5-42bb-ad14-1d5f795b8eaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBPX-10A (Blood Derived Normal), aliquot TARGET-10-PARBPX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8942c287-ead1-45eb-8cf3-df0ab04a5410

The open-access MAF lists 476 somatic variants for this specimen: 260 protein-altering or splice-affecting, 101 silent, 115 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, Silent 101, Intron 59, Nonsense Mutation 27, 3'UTR 18, 5'UTR 17, RNA 12, Splice Site 5, 3'Flank 5, 5'Flank 4, Frame Shift Ins 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7474C>T p.Q2492* (on ENST00000358273 / NM_001042492.3; = p.Q2471* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as rs1555536340, CM032013, COSV62193242; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPS1 | c.1843C>T p.Q615* (on ENST00000220888 / NM_001330599.2; = p.Q628* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as rs1554595930, CM154759; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM20 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1330071325; called by muse, mutect2, varscan2
- AHCYL2 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61486984; called by muse, mutect2, varscan2
- ALB | c.97C>G p.H33D | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV55739677; called by muse, mutect2, varscan2
- ANK2 | c.1813C>T p.H605Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs898855441; called by muse, mutect2, varscan2
- ANK3 | c.10627G>C p.D3543H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1179851287; called by muse, mutect2, varscan2
- ATP2B1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV99665356; called by muse, mutect2, varscan2
- BCL11B | c.386C>G p.S129* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV61736765; called by muse, mutect2, varscan2
- BSN | c.10570G>A p.G3524S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.594); catalogued as rs776240584, COSV56529823; called by muse, mutect2, varscan2
- C2CD2 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs748440809; called by muse, mutect2, varscan2
- C8A | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.824); catalogued as COSV100776575; called by muse, varscan2
- CAD | c.4196G>A p.G1399E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV53027357; called by muse, mutect2, varscan2
- CAPN14 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV67291711; called by muse, mutect2, varscan2
- CCDC180 | c.3767G>C p.G1256A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV63827248; called by muse, mutect2, varscan2
- CD63 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs1007732005; called by muse, mutect2, varscan2
- CDH15 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs779129115, COSV57023379; called by muse, mutect2, varscan2
- CDH18 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as rs1423504904, COSV56964904; called by muse, mutect2, varscan2
- CDH9 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV50255585, COSV50410455; called by muse, mutect2, varscan2
- CFAP43 | c.4781G>A p.R1594Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as rs777903301; called by muse, mutect2, varscan2
- CHD8 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as rs767231058; called by muse, mutect2, varscan2
- CHRDL1 | c.185C>T p.S62L (on ENST00000372045; = p.S68L on NM_145234.4) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs901776843, COSV54323474; called by muse, mutect2, varscan2
- COL6A5 | c.3541G>A p.E1181K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs1361020749; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs928896343; called by muse, mutect2, varscan2
- CRACD | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV51718064; called by muse, mutect2, varscan2
- CRPPA | c.982C>A p.Q328K (on ENST00000407010 / NM_001368197.1; = p.Q278K on NM_001101417.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV101235313; called by muse, mutect2, varscan2
- CTCF | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50483382, COSV50520486; called by muse, mutect2, varscan2
- CXorf58 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs753173434, COSV64858200; called by muse, mutect2, varscan2
- CYP2A6 | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs537280653, COSV104397075; called by muse, mutect2, varscan2
- CYP4F11 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV56128007; called by muse, mutect2, varscan2
- DBNDD1 | c.382G>C p.E128Q (on ENST00000002501 / NM_001042610.3; = p.E148Q on NM_024043.3) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV99136417, COSV99136541; called by muse, mutect2
- DCLK2 | c.1967C>A p.S656Y | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.492); catalogued as rs763520035; called by muse, mutect2, varscan2
- DIAPH2 | c.2948C>G p.S983* | Nonsense Mutation (SNP) | VAF 43/96 reads (45%) | catalogued as COSV61271031; called by muse, mutect2, varscan2
- DIP2A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376553079; called by muse, mutect2, varscan2
- DLEC1 | c.4112C>T p.S1371L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100343045; called by muse, mutect2, varscan2
- DNAH7 | c.4466C>T p.S1489L | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337644440; called by muse, mutect2
- DOCK10 | c.1545G>C p.L515F | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772442937; called by muse, mutect2, varscan2
- DPP6 | c.1798G>A p.E600K (on ENST00000377770 / NM_001364500.2; = p.E538K on NM_001936.5) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV59643768; called by muse, mutect2, varscan2
- EIF3H | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 65/145 reads (45%) | catalogued as COSV52671104; called by muse, mutect2, varscan2
- FANCM | c.2306G>A p.R769K | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as rs548624235; called by muse, mutect2, varscan2
- FOXK1 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100195602; called by mutect2, varscan2
- GRHL3 | c.1339C>T p.R447W (on ENST00000350501 / NM_198174.3; = p.R452W on NM_021180.3) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs138087584; called by muse, mutect2, varscan2
- GRK5 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs1381942896, COSV64866701; called by muse, mutect2
- HEATR5A | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1467007105; called by muse, mutect2
- HERC1 | c.4483G>C p.E1495Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.954); catalogued as COSV71247174; called by muse, mutect2, varscan2
- HERC5 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs777948130; called by muse, mutect2, varscan2
- HHIPL2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564422; called by muse, mutect2, varscan2
- HSPB2 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57051259; called by muse, mutect2, varscan2
- ITGA1 | c.497-1G>C p.X166_splice | Splice Site (SNP) | VAF 27/52 reads (52%) | catalogued as COSV50877286, COSV50897777; called by muse, mutect2, varscan2
- KANK4 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.118); catalogued as rs1315873891, COSV100586989; called by muse, mutect2, varscan2
- KIAA1549L | c.569C>G p.S190C (on ENST00000321505; = p.S487C on NM_012194.3) | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV104377835, COSV55776788; called by muse, mutect2, varscan2
- KIAA2026 | c.4577C>T p.S1526L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs899549008; called by muse, mutect2, varscan2
- KLF15 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs758256673; called by muse, mutect2, varscan2
- LARP1B | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1561278673; called by muse, mutect2, varscan2
- LONRF2 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1212831593, COSV66542634; called by muse, mutect2, varscan2
- LRP6 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV53794829; called by muse, mutect2, varscan2
- MED14 | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100247597; called by muse, mutect2, varscan2
- MEFV | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54828598; called by muse, mutect2
- MIGA1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV100889812; called by muse, mutect2, varscan2
- MTMR9 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs1289326218; called by muse, mutect2, varscan2
- MYPN | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1187225110; called by muse, mutect2, varscan2
- NCKAP5 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV58479876; called by muse, mutect2, varscan2
- NOL4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.569); catalogued as COSV99307638; called by muse, mutect2, varscan2
- NRG2 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.449); catalogued as COSV56840708; called by muse, mutect2, varscan2
- NRM | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs770705366; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUTM1 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV59216978; called by muse, mutect2, varscan2
- PARM1 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747256833; called by muse, mutect2, varscan2
- PCLO | c.14101C>G p.Q4701E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61622164; called by muse, mutect2, varscan2
- PDLIM5 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100524024, COSV58748810; called by muse, mutect2, varscan2
- PLAU | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV65642058; called by muse, mutect2, varscan2
- PPFIA2 | c.3556-1G>C p.X1186_splice | Splice Site (SNP) | VAF 31/73 reads (42%) | catalogued as COSV100334311; called by muse, mutect2, varscan2
- PRDM12 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV53391145; called by muse, varscan2
- PREPL | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV53219280; called by muse, mutect2, varscan2
- RAC3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); catalogued as rs1336881634, COSV60712748; called by muse, mutect2, varscan2
- ROBO2 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100168358, COSV100170181; called by muse, mutect2, varscan2
- RPP30 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as rs372840568; called by muse, mutect2, varscan2
- RWDD2B | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.323); catalogued as COSV54501799; called by muse, mutect2, varscan2
- SBF2 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.424); catalogued as rs771104991; called by muse, mutect2, varscan2
- SCIN | c.960G>A p.M320I (on ENST00000297029 / NM_001112706.3; = p.M73I on NM_033128.3) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV51689509, COSV51698861; called by muse, mutect2, varscan2
- SLC29A2 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as rs765545997, COSV60804381; called by mutect2, varscan2
- SMARCD1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV56547271; called by muse, mutect2, varscan2
- SNTG1 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52434501; called by muse, mutect2, varscan2
- SOST | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as rs758338208; called by muse, mutect2, varscan2
- SSX2IP | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100642668; called by muse, mutect2
- STKLD1 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs782277387, COSV100911963; called by muse, mutect2, varscan2
- TBX10 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59009389; called by muse, mutect2, varscan2
- TCF25 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1408589755; called by muse, mutect2, varscan2
- TSC2 | c.4013C>G p.S1338* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV51917907; called by muse, mutect2, varscan2
- UBN1 | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1278829323, COSV52167293; called by muse, mutect2, varscan2
- VSTM2A | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.195); catalogued as COSV100173375; called by muse, mutect2, varscan2
- WDR13 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.721); catalogued as rs782539827, COSV54333739; called by muse, mutect2, varscan2
- ZBTB49 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV61924373; called by muse, mutect2, varscan2
- ZBTB49 | c.1773G>C p.E591D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100552371, COSV100552656; called by muse, mutect2, varscan2
- ZFPM2 | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 22/129 reads (17%) | catalogued as COSV65874969; called by muse, mutect2, varscan2
- ZFR2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1568423492; called by muse, mutect2, varscan2
- ZNF273 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as COSV60398019, COSV60398545; called by muse, mutect2, varscan2
- ZNF470 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV57969121; called by muse, mutect2, varscan2
- ZNF701 | c.797C>T p.S266L (on ENST00000301093; = p.S200L on NM_018260.3) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV56527744; called by muse, mutect2, varscan2
- ZNF883 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101432543; called by muse, mutect2, varscan2
- ZSWIM3 | c.2065C>G p.P689A | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs1486415645, COSV54850457; called by muse, mutect2, varscan2
- ACAA1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | called by muse, varscan2
- ACOX2 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ACSM2A | c.1180-1G>A p.X394_splice (on ENST00000219054; = p.X315_splice on NM_001308169.2) | Splice Site (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ADAMTS5 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ADGRG6 | c.3517C>G p.L1173V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AFTPH | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AMMECR1L | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ANAPC2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.471); called by muse, mutect2
- ARPC3 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2
- ATF7IP | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ATIC | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- ATXN7 | c.1310C>G p.S437* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- AVIL | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BABAM2 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- BACH2 | c.785_786del p.S262* | Frame Shift Del (DEL) | VAF 33/112 reads (29%) | called by pindel, varscan2
- BDP1 | c.2455G>A p.G819R | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- BIRC6 | c.2204C>G p.S735* | Nonsense Mutation (SNP) | VAF 58/121 reads (48%) | called by muse, mutect2, varscan2
- BLOC1S4 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BNIP2 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- C2CD2 | c.1779G>C p.W593C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2orf16 | c.3813G>C p.Q1271H | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- C8A | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, varscan2
- CACNA1F | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASK | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- CASP8AP2 | c.1276C>G p.H426D | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CCT6A | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CHAF1A | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD1L | c.192G>C p.Q64H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- CLDN8 | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL11A2 | c.4595G>A p.G1532E (on ENST00000341947 / NM_080680.3; = p.G1425E on NM_080679.2) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- COL22A1 | c.3194G>C p.R1065P | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A5 | c.3126G>A p.M1042I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPB2 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSRNP3 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CYP2A13 | c.867G>C p.K289N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CYP4V2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DEF6 | c.1670G>C p.G557A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- DEPDC5 | c.2462C>G p.S821* (on ENST00000400246; = p.S890* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- DGKD | c.1954G>C p.E652Q (on ENST00000264057 / NM_152879.3; = p.E608Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- DNAH10 | c.6463G>T p.D2155Y (on ENST00000409039; = p.D2094Y on NM_207437.3) | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAJC3 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNASE2B | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DNMBP | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- DNMBP | c.2828C>T p.S943F | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- DOK6 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOP1B | c.3500C>T p.S1167L | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2
- DST | c.17809C>G p.Q5937E (on ENST00000361203 / NM_001374722.1; = p.Q3634E on NM_015548.5) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ECHDC1 | c.47C>T p.S16F (on ENST00000531967 / NM_001139510.1; = p.S10F on NM_018479.3) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF3CL | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FANCB | c.2324C>T p.S775F | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT4 | c.8308G>A p.D2770N | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FETUB | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- FREM2 | c.8623G>C p.D2875H | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FSIP2 | c.18002C>T p.S6001L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- GLI2 | c.2068T>G p.S690A (on ENST00000361492 / NM_001374353.1; = p.S707A on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- GOLGA1 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- GOLGA4 | c.1555C>G p.Q519E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- GPRASP1 | c.2530G>A p.G844R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GRK5 | c.1543-1G>A p.X515_splice | Splice Site (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- HDAC6 | c.1662G>A p.M554I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- HEATR1 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- HELZ | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HERC2 | c.7705G>C p.E2569Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HORMAD1 | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IDH3G | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- IGLV3-21 | c.346_347insTT p.P116Lfs*? | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- JAZF1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- JRK | c.1685C>G p.S562* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- KCNH1 | c.1455G>A p.M485I (on ENST00000271751 / NM_172362.3; = p.M458I on NM_002238.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- KDM4D | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM7A | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KIF26B | c.3062C>G p.S1021* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- KPNA5 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KY | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- LHFPL1 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP1 | c.4285G>C p.E1429Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.963); called by muse, mutect2
- MAN2A1 | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MARVELD2 | c.276del p.K93Rfs*70 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | called by pindel, varscan2
- MARVELD2 | c.1124G>C p.R375T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MBP | c.871-3C>T | Splice Region (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- MCF2 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- MCF2L | c.570G>A p.M190I (on ENST00000375608; = p.M158I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2
- MDC1 | c.2929C>T p.P977S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MEIOC | c.1825C>G p.Q609E | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- MICAL3 | c.5558T>C p.I1853T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MLH3 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MMP20 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- MOB1B | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOV10L1 | c.1154G>C p.G385A | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MPG | c.516C>G p.S172R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MROH2A | c.4838G>A p.G1613E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MTERF3 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- MUC5B | c.16203C>G p.F5401L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by mutect2, varscan2
- MYH13 | c.3985G>C p.A1329P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYO3A | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MYO5A | c.3574G>A p.E1192K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MZB1 | c.414-7C>T | Splice Region (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- NCBP1 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- NDFIP2 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEXMIF | c.3888G>A p.M1296I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC4 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- NR2F1 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- NSMCE3 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OBI1 | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OR4D1 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR51T1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- PAPPA | c.2502C>G p.F834L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHGA4 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PDCD11 | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDGFRA | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PDZD2 | c.4781C>G p.S1594* | Nonsense Mutation (SNP) | VAF 50/118 reads (42%) | called by muse, mutect2, varscan2
- PHACTR2 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PI4KA | c.4376C>G p.S1459C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PIP4K2A | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PPFIA4 | c.2808+2T>C p.X936_splice (on ENST00000447715; = p.X937_splice on NM_001304331.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- PRRC2C | c.1807G>A p.E603K (on ENST00000367742; = p.E601K on NM_015172.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RACGAP1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RAPH1 | c.1781G>C p.R594T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RASD2 | c.741C>G p.I247M | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RASGRP3 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- RNASEL | c.1277_1280delinsTGTGGC p.H426Lfs*68 | Frame Shift Ins (INS) | VAF 22/64 reads (34%) | called by pindel, varscan2*
- RNF40 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SCAF4 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- SEMG2 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC36A4 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC38A10 | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SLC45A2 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2
- SLC6A14 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SNRNP200 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.097); called by muse, mutect2
- SPATA31E1 | c.4116G>T p.M1372I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- STS | c.1357C>G p.Q453E | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- STYX | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SUPT3H | c.688G>A p.E230K (on ENST00000371460 / NM_181356.3; = p.E219K on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNPO2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCIRG1 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.102); called by muse, mutect2
- TET2 | c.5461G>A p.D1821N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- THAP5 | c.1054G>A p.E352K (on ENST00000415914 / NM_001130475.3; = p.E310K on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- THOC1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TIMP1 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR2 | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TMEM143 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TRMT13 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TSSK2 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TUT4 | c.3750C>G p.F1250L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- TXN | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBA2 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UGGT2 | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- USP37 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- VCPIP1 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- VWA1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- ZBED6 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZDHHC15 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- ZNF471 | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ZNF556 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF568 | c.1544C>G p.S515* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- ZNF615 | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF713 | c.790C>T p.Q264* (on ENST00000633730 / NM_001366796.2; = p.Q277* on NM_182633.3) | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- ZNF768 | c.1038G>C p.K346N | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ABCB8 | c.948C>A p.L316= (on ENST00000297504 / NM_001282291.2; = p.L299= on NM_007188.5) | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV52511672; called by muse, mutect2, varscan2
- ACAA1 | c.477G>A p.G159= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs760218287; called by muse, varscan2
- ADGB | c.2385G>A p.L795= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs944027491, COSV58864779; called by muse, mutect2, varscan2
- AHNAK | c.14256C>A p.G4752= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as COSV57223598; called by muse, mutect2, varscan2
- AHNAK2 | c.582C>T p.L194= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- ALOX5 | c.1662C>T p.V554= | Silent (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
- ANKRD2 | c.819C>T p.I273= | Silent (SNP) | VAF 43/58 reads (74%) | called by muse, mutect2, varscan2
- ARVCF | c.2505G>A p.L835= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- ASB17 | c.669C>G p.V223= | Silent (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- ATP11A | c.2400G>A p.A800= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs749074821; called by muse, mutect2
- ATP7A | c.270G>A p.L90= | Silent (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
- ATR | c.1578G>A p.K526= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV63391375; called by muse, mutect2, varscan2
- BANK1 | c.2007C>T p.L669= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1307334465; called by muse, mutect2, varscan2
- BMP15 | c.996C>G p.L332= | Silent (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- BMPER | c.1623A>G p.P541= | Silent (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- BRI3BP | c.588C>T p.F196= | Silent (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- C6 | c.1390C>T p.L464= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as rs1390096543; called by muse, mutect2, varscan2
- CEP57L1 | c.981G>A p.L327= | Silent (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- COL6A3 | c.7545C>T p.F2515= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs779344562; called by muse, mutect2, varscan2
- CTNNA2 | c.1788G>C p.L596= | Silent (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- CYRIA | c.15C>G p.L5= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- DGKB | c.786G>C p.L262= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- DGKK | c.3285G>A p.L1095= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- DNAH5 | c.9735G>C p.V3245= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV54234572; called by muse, mutect2, varscan2
- DNAH9 | c.6270C>T p.F2090= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs1456931967, COSV52350653; called by muse, mutect2, varscan2
- DNAJA1 | c.39C>T p.V13= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs1212658598; called by muse, mutect2, varscan2
- DPH7 | c.1215G>A p.K405= | Silent (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- EMC1 | c.528G>A p.Q176= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- FAM161B | c.1998C>T p.F666= (on ENST00000651776; = p.F603= on NM_152445.3) | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- FARP2 | c.2247C>T p.L749= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV50870044, COSV50874442; called by muse, mutect2, varscan2
- FBXL7 | c.153G>A p.L51= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs759150149; called by muse, mutect2, varscan2
- FGD6 | c.4125G>A p.E1375= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- FIGN | c.417C>T p.L139= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs375449325; called by muse, mutect2, varscan2
- FLNC | c.2487C>T p.F829= | Silent (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- FOXG1 | c.1068C>T p.F356= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- FREM3 | c.6297G>A p.E2099= | Silent (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- GLIPR2 | c.300G>A p.G100= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs759112042; called by muse, mutect2, varscan2
- GRM1 | c.837G>A p.E279= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- HDHD3 | c.700C>T p.L234= | Silent (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- HSPG2 | c.11436G>C p.L3812= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- IARS2 | c.1929G>A p.R643= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as COSV56962658; called by muse, mutect2, varscan2
- IGF2BP2 | c.1458C>T p.F486= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV60486173; called by muse, mutect2, varscan2
- ITGA7 | c.2212C>T p.L738= (on ENST00000555728; = p.L694= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- KCTD8 | c.189C>T p.L63= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV63585429; called by muse, mutect2, varscan2
- KIF16B | c.24G>C p.V8= | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- LRRC7 | c.2148G>A p.L716= (on ENST00000651989 / NM_001370785.2; = p.L683= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV50467751, COSV50641289; called by muse, mutect2, varscan2
- LTK | c.1776G>C p.L592= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV53027092; called by muse, mutect2, varscan2
- MAGI2 | c.285C>G p.L95= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- MAGI3 | c.2214C>T p.F738= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV56840641; called by muse, mutect2
- MDN1 | c.337C>T p.L113= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV65522549; called by muse, mutect2, varscan2
- MED16 | c.1011C>G p.L337= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV54131194; called by muse, mutect2, varscan2
- METTL11B | c.120G>A p.Q40= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- MYD88 | c.223C>T p.L75= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- NAMPT | c.126G>A p.K42= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- NDUFAB1 | c.42C>T p.P14= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs769794674; called by muse, mutect2, varscan2
- NELL1 | c.1920G>A p.L640= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- NMUR2 | c.495G>A p.R165= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs891893148, COSV54919440, COSV54919973; called by muse, mutect2, varscan2
- OR4K5 | c.918G>C p.L306= | Silent (SNP) | VAF 16/243 reads (7%) | catalogued as COSV100262275; called by muse, mutect2
- OR5AP2 | c.60C>G p.L20= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV57258277; called by muse, mutect2, varscan2
- OR5D14 | c.606C>T p.F202= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs866261956; called by muse, mutect2
- PCDH7 | c.1062G>C p.V354= | Silent (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- PHEX | c.954C>T p.I318= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV101040106; called by muse, mutect2, varscan2
- PIK3CG | c.2133G>A p.Q711= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV63249504; called by muse, mutect2, varscan2
- PLEKHG4B | c.2901C>T p.L967= (on ENST00000283426; = p.L1323= on NM_052909.5) | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- POGLUT3 | c.882C>T p.L294= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- POLR2A | c.2454G>A p.E818= | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2
- POLR2B | c.819C>T p.F273= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV58900521; called by muse, mutect2, varscan2
- PTH1R | c.1131C>G p.L377= | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- PTPRD | c.2052G>A p.R684= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- RRP1 | c.390G>A p.L130= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs1220235725; called by muse, mutect2, varscan2
- RXRA | c.474C>T p.F158= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- RYR2 | c.2196C>G p.L732= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV63678562; called by muse, mutect2, varscan2
- SAC3D1 | c.696C>T p.F232= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV57246864; called by muse, mutect2, varscan2
- SCGB1D2 | c.258G>A p.K86= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV55274871; called by muse, mutect2, varscan2
- SECISBP2 | c.1329G>A p.K443= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- SEL1L3 | c.3330G>A p.V1110= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- SLC5A8 | c.1360C>T p.L454= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV73310840; called by muse, mutect2, varscan2
- SLC9A7 | c.1794C>T p.F598= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1677C>T p.L559= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as rs780312673; called by muse, mutect2, varscan2
- SMC1B | c.702G>A p.K234= | Silent (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- SMC4 | c.3198C>T p.I1066= | Silent (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- SNTG1 | c.1035C>T p.L345= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV52474775, COSV99383845; called by muse, mutect2, varscan2
- SPATA1 | c.387T>C p.V129= | Silent (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- ST14 | c.1452C>G p.L484= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- STYXL2 | c.1965G>A p.G655= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV54810107; called by muse, mutect2, varscan2
- SWSAP1 | c.117C>T p.F39= (on ENST00000312423; = p.F60= on NM_175871.4) | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- TAF1A | c.306C>T p.L102= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs751467054, COSV61920046; called by muse, mutect2, varscan2
- TET1 | c.1887G>A p.K629= | Silent (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- TMEM61 | c.483G>C p.S161= | Silent (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- TPR | c.117G>A p.L39= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1402738893, COSV55216655; called by muse, mutect2, varscan2
- TTC39B | c.795C>G p.L265= | Silent (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- VARS1 | c.1998G>A p.S666= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs765077498, COSV63304563; called by muse, mutect2, varscan2
- VPS9D1 | c.1740G>C p.L580= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- VWA5B1 | c.1569C>T p.P523= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- VWA8 | c.5487G>A p.L1829= | Silent (SNP) | VAF 6/135 reads (4%) | called by muse, mutect2
- WDR81 | c.2055G>A p.A685= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1320621451; called by muse, mutect2
- Z83844.2 | c.1584C>T p.F528= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs755025302, COSV53216352; called by muse, mutect2, varscan2
- ZEB1 | c.2460G>A p.Q820= | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- ZNF417 | c.948T>C p.R316= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV56309871; called by muse, mutect2
- ZNF462 | c.5664G>A p.Q1888= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs892283956; called by muse, mutect2, varscan2
- ZNF491 | c.429C>T p.L143= | Silent (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- ABCA6 | c.1903-35G>C | Intron (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+8154C>G | Intron (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- AC007342.3 | n.370G>C | RNA (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- AC069544.2 | c.-148G>A | 5'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- AC094103.1 | n.384C>T | RNA (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- AC136777.1 | n.58C>T | RNA (SNP) | VAF 10/38 reads (26%) | catalogued as rs988546412; called by muse, mutect2, varscan2
- AC245047.1 | n.166G>A | RNA (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- ACAA1 | c.997+102G>A | Intron (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- ACTB | c.364-108A>T | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.1983-365C>G | Intron (SNP) | VAF 48/119 reads (40%) | called by muse, mutect2, varscan2
- ALDH6A1 | c.*3652G>C | 3'UTR (SNP) | VAF 58/113 reads (51%) | called by muse, mutect2, varscan2
- AMOT | c.*22G>A | 3'UTR (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- ANAPC11 | c.110-416C>T | Intron (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- AOC4P | n.1597+49C>T | Intron (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- APOOP5 | chr16:59751984 C>T | 3'Flank (SNP) | VAF 10/97 reads (10%) | catalogued as rs1258786477; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+49G>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- BCL2L15 | c.-101G>C | 5'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- BEST3 | c.482-5547G>A | Intron (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2
- BET1 | c.*444C>T | 3'UTR (SNP) | VAF 14/85 reads (16%) | catalogued as rs1562806232; called by muse, mutect2, varscan2
- BFSP1 | c.-179G>T | 5'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+4164C>T | Intron (SNP) | VAF 6/139 reads (4%) | catalogued as rs1428559152; called by muse, mutect2
- CAGE1 | c.2005-39G>C | Intron (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- CALM2 | c.3+45G>A | Intron (SNP) | VAF 7/44 reads (16%) | catalogued as rs1284948002; called by muse, mutect2, varscan2
- CBLL1 | c.182-843G>A | Intron (SNP) | VAF 53/141 reads (38%) | catalogued as rs1403712624; called by muse, mutect2, varscan2
- CCDC7 | c.1802-10508C>A | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- CD44 | c.797-163C>A | Intron (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- CDH8 | c.1537-56G>A | Intron (SNP) | VAF 31/71 reads (44%) | catalogued as rs897538122; called by muse, mutect2, varscan2
- CENPS-CORT | c.51+797G>A | Intron (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- CHGB | c.*138G>A | 3'UTR (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- CPA3 | c.*19G>A | 3'UTR (SNP) | VAF 8/36 reads (22%) | catalogued as rs773048186; called by muse, mutect2, varscan2
- CXCL12 | c.*7C>G | 3'UTR (SNP) | VAF 52/73 reads (71%) | catalogued as COSV100638928; called by muse, mutect2, varscan2
- CYB5R2 | c.388+231C>G | Intron (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- DIO3OS | chr14:101552549 G>A | 3'Flank (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- DOCK1 | c.*75C>G | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- DPF1 | c.676+60C>G | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as rs759782498; called by muse, mutect2, varscan2
- ECPAS | c.-107C>G | 5'UTR (SNP) | VAF 7/12 reads (58%) | catalogued as rs199992999, COSV52192087; called by muse, mutect2, varscan2
- EGF | c.941-12C>T | Intron (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- EIPR1 | c.260-16958G>C | Intron (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- ERCC6 | c.2829+107C>T | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- FAM183BP | n.1197G>A | RNA (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- FBXL4 | c.-23G>A | 5'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- FBXO4 | c.646+73C>G | Intron (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- FKBP3 | c.-51G>A | 5'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99361140; called by muse, mutect2
- GPC1 | c.883+60C>T | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2
- GPS2 | c.398-30C>G | Intron (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-4328G>C | Intron (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- GVINP1 | n.3422G>A | RNA (SNP) | VAF 48/118 reads (41%) | catalogued as rs990473860; called by muse, mutect2, varscan2
- HINT1 | c.217-1262C>G | Intron (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- HMGCL | c.876+85G>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- HOPX | chr4:56657819 G>A | 5'Flank (SNP) | VAF 12/33 reads (36%) | catalogued as rs1053807949; called by muse, mutect2, varscan2
- HUS1 | c.-52G>C | 5'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2
- IGIP | c.*9G>A | 3'UTR (SNP) | VAF 34/86 reads (40%) | catalogued as rs755897477, COSV60964511; called by muse, mutect2, varscan2
- IRAK1BP1 | c.*4678C>G | 3'UTR (SNP) | VAF 61/139 reads (44%) | called by muse, mutect2, varscan2
- KMT5A | c.289+56C>T | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as rs572869728; called by muse, mutect2, varscan2
- KMT5B | c.377+468C>T | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- KRAS | c.*38G>A | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- LOXL3 | c.*570G>C | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, varscan2
- LRBA | c.6363+8751C>T | Intron (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- MAST4 | c.674+30870G>A | Intron (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- MIR1915 | chr10:21495601 C>T | 3'Flank (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- MIR520H | n.47G>A | RNA (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- MKS1 | c.418-124G>C | Intron (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- MRPS23 | c.44+53C>T | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as rs1210815574; called by muse, mutect2, varscan2
- MUC21 | c.-82C>G | 5'UTR (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- MVD | chr16:88663132 C>A | 5'Flank (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- MYADML | n.435G>C | RNA (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- MYD88 | c.645-9C>G | Intron (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- MYO1B | c.2470-112C>G | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- NAALADL1 | c.1078+45T>C | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- NCAM1 | c.1954-10C>G | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- NCL | c.-17C>A | 5'UTR (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- NINJ2 | c.33+19500G>A | Intron (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2
- NLRP1 | c.-104G>C | 5'UTR (SNP) | VAF 8/15 reads (53%) | catalogued as rs771875198; called by muse, varscan2
- NOC2LP2 | n.747G>A | RNA (SNP) | VAF 24/58 reads (41%) | catalogued as rs1240432367; called by muse, mutect2, varscan2
- NT5DC3 | c.1020-10C>G | Intron (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- NUTM1 | c.*101G>T | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- PDK3 | chrX:24539248 C>T | 3'Flank (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- PDXDC1 | c.22-9330C>T | Intron (SNP) | VAF 10/49 reads (20%) | catalogued as rs1019283846; called by muse, mutect2, varscan2
- PIKFYVE | c.1320+28G>A | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- PKNOX2 | c.-130+23868G>A | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- PLEKHA1 | c.-20-36C>T | Intron (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- POLL | c.1364-12C>T | Intron (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- PPT1 | c.232-99C>T | Intron (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- PRRT1 | chr6:32152163 G>A | 5'Flank (SNP) | VAF 40/82 reads (49%) | catalogued as rs1413254451; called by muse, mutect2, varscan2
- PTPN1 | c.-68G>A | 5'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- PYGO1 | c.49+821C>T | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- RAP1B | c.*30+77G>C | Intron (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- RBIS | c.114+186G>C | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.805G>A | RNA (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- RNASET2 | c.446+143C>G | Intron (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- SCN9A | c.*68G>A | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- SHTN1 | c.112-5170C>T | Intron (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- SNORD116-11 | chr15:25079246 G>A | 3'Flank (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- SNX12 | c.-7C>T | 5'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as rs1197117412, COSV52145742; called by muse, mutect2, varscan2
- SOGA1 | c.*8819G>A | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- SPX | c.-153G>C | 5'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- STK32A | c.1032+62G>C | Intron (SNP) | VAF 19/43 reads (44%) | catalogued as rs1226987182; called by muse, mutect2, varscan2
- STK32A | c.1033-109C>T | Intron (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- STXBP4 | c.*43G>C | 3'UTR (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- SYCE2 | c.-33G>C | 5'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- TATDN1 | c.-12C>T | 5'UTR (SNP) | VAF 10/93 reads (11%) | catalogued as rs369976535; called by muse, mutect2, varscan2
- TCIRG1 | c.*60G>C | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- TIA1 | c.583+94G>C | Intron (SNP) | VAF 15/35 reads (43%) | catalogued as rs769801612; called by muse, mutect2, varscan2
- TIAM1 | chr21:31559403 G>C | 5'Flank (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- TIMM22 | c.*1G>C | 3'UTR (SNP) | VAF 7/12 reads (58%) | catalogued as rs749976361; called by muse, mutect2, varscan2
- TMC6 | c.1715+149C>G | Intron (SNP) | VAF 28/58 reads (48%) | catalogued as COSV100130086; called by muse, mutect2, varscan2
- TRADD | c.152-367G>C | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as rs1290285888; called by muse, mutect2, varscan2
- TRIM45 | c.-27C>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- TSEN34 | c.-121G>A | 5'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- XIST | n.7661C>T | RNA (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- Z82195.2 | n.416-19536G>A | Intron (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- ZMAT1 | c.121+6667C>G | Intron (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- ZNF485 | c.*143G>T | 3'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- ZNF674 | c.253+5203G>C | Intron (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- ZNF849P | n.1563G>C | RNA (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
